Gene-level copy-number profile of tumor specimen ALCH-B47C-TTP1-A from ALCHEMIST case ALCH-B47C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.9 years (27,737 days).
Specimen ALCH-B47C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5997dc55-4042-4797-bb9e-240c5db367bc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B47C-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/fa2fc1b5-cb03-4b52-a5dc-6b686b81864f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 4,721; copy number 2: 51,089; copy number 3: 1,983; copy number 4: 556; copy number 5: 17; copy number 8: 1; copy number 9: 8; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,616,836–10,617,115, 1 gene (within-gene range 0–1): RN7SL614P.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr15:25,176,832–25,178,819, 2 genes (within-gene range 0–2): SNORD115-4, SNORD115-5.
- chr15:25,184,306–25,206,343, 13 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20.
- chr15:77,894,684–77,904,674, 1 gene: CSPG4P13.
- chr18:37,305,295–37,306,333, 1 gene (within-gene range 0–2): AC090386.2.
- chr22:18,846,811–18,861,049, 2 genes (within-gene range 0–5): AC008132.1, BCRP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,650,966, 17 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr22:18,533,646–18,653,617, 8 genes, copy number 9: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,733,914–18,757,906, 1 gene, copy number 8: FAM230E.
- chr22:18,873,543–18,894,407, 2 genes, copy number 11: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 4,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
